Gene-level copy-number profile of tumor specimen TCGA-ER-A19T-01A from TCGA case TCGA-ER-A19T, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acral lentiginous melanoma, malignant; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.5 years (18,802 days).
Specimen TCGA-ER-A19T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6d494e5c-1758-4100-82b8-03626e817f91.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8ea672ba-66f5-4956-9477-dfe2f7c5a8ab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,385; copy number 2: 14,402; copy number 3: 17,616; copy number 4: 12,971; copy number 5: 9,600; copy number 6: 1,948; copy number 7: 918; copy number 8: 331; copy number 9: 82; copy number 10: 38; copy number 11: 72; copy number 13: 22; copy number 15: 14; copy number 17: 33; copy number 19: 70; copy number 20: 116; copy number 21: 2; copy number 23: 28; copy number 25: 1; copy number 26: 24; copy number 28: 1; copy number 29: 28; copy number 30: 3; copy number 31: 17; copy number 40: 46; copy number 44: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19T-01A-11D-A192-01): tumor purity 0.97, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,882 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:33,433,510–33,693,993, 2 genes, copy number 13: AC097535.1, AC079772.1.
- chr4:38,276,178–45,480,136, 131 genes, copy number 7–17 (broad region; genes not listed).
- chr6:66,710,242–66,728,904, 2 genes, copy number 7: AL450336.1, RNU7-66P.
- chr7:38,257,879–38,311,808, 8 genes, copy number 10: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:44,044,640–44,369,292, 15 genes, copy number 7 (within-gene range 5–7): DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2.
- chr8:43,672,823–49,229,174, 66 genes, copy number 11 (broad region; genes not listed).
- chr8:51,257,688–51,321,118, 1 gene, copy number 21: AC012413.1.
- chr8:51,435,602–51,436,509, 1 gene, copy number 21: BRIX1P1.
- chr8:53,162,339–53,251,637, 3 genes, copy number 30: AC009646.1, AC009646.2, OPRK1.
- chr8:54,042,989–54,247,906, 8 genes, copy number 19: AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1.
- chr8:54,381,698–54,479,963, 5 genes, copy number 11: AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 11: SEC11B.
- chr8:120,913,065–122,428,551, 9 genes, copy number 7 (within-gene range 6–7): AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3, SMILR.
- chr8:122,485,515–122,489,815, 1 gene, copy number 7: AC108136.1.
- chr8:126,552,443–127,742,951, 17 genes, copy number 7: LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:128,634,199–129,844,504, 10 genes, copy number 9 (within-gene range 5–9): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5.
- chr8:129,864,478–129,868,716, 2 genes, copy number 9: AC022973.2, AC022973.1.
- chr8:135,457,456–139,463,016, 19 genes, copy number 7 (within-gene range 6–7): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1.
- chr8:140,505,813–141,662,209, 31 genes, copy number 8: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1.
- chr11:67,483,026–71,252,577, 116 genes, copy number 20 (broad region; genes not listed).
- chr11:73,400,487–73,598,189, 1 gene, copy number 8 (within-gene range 5–8): FAM168A.
- chr11:73,510,658–74,498,533, 39 genes, copy number 8–23: AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2.
- chr11:76,404,140–79,441,030, 66 genes, copy number 13–40 (within-gene range 2–40) (broad region; genes not listed).
- chr11:86,374,736–89,301,477, 53 genes, copy number 31–44: CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3, AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1, GRM5, RNU6-16P, TYR, CBX3P7, AP000720.1, AP000720.2.
- chr11:101,129,077–101,872,562, 5 genes, copy number 29 (within-gene range 4–29): PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1.
- chr12:29,658,376–50,283,546, 398 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr15:19,878,555–22,617,854, 139 genes, copy number 8 (broad region; genes not listed).
- chr15:46,099,193–46,100,392, 1 gene, copy number 28: AC068714.1.
- chr15:46,693,288–46,804,844, 1 gene, copy number 26 (within-gene range 2–26): AC073941.1.
- chr15:46,827,526–48,343,373, 23 genes, copy number 26: AC073941.2, AC066615.1, SEMA6D, RN7SKP139, AC084882.1, AC023905.1, AC009558.1, AC009558.2, AC012050.1, AC044787.1, LINC01491, AC092078.2, AC092078.1, AC092078.3, SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT.
- chr15:49,155,656–49,367,869, 1 gene, copy number 19 (within-gene range 5–19): GALK2.
- chr15:49,198,900–52,529,050, 84 genes, copy number 19–29 (within-gene range 4–29) (broad region; genes not listed).
- chr15:55,056,723–55,092,177, 1 gene, copy number 25: AC025272.1.
- chr15:90,102,649–90,816,166, 34 genes, copy number 7: IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1, CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2.
- chr17:29,560,547–30,108,452, 26 genes, copy number 7 (within-gene range 2–7): ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2.
- chr17:52,390,515–72,058,073, 463 genes, copy number 7–8 (broad region; genes not listed).
- chr17:72,072,333–72,103,035, 1 gene, copy number 8 (within-gene range 6–8): LINC02097.
- chr17:79,089,345–79,516,148, 1 gene, copy number 8 (within-gene range 6–8): RBFOX3.
- chr17:79,598,032–80,209,331, 23 genes, copy number 8 (within-gene range 6–8): AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14.
- chr19:51,184,905–52,095,765, 73 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,385. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
